Surgical pathology report (de-identified scan), TCGA case TCGA-F7-A61W, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-F7-A61W-01A (Primary Tumor).

Gross Description: Tumor is located in Left oral tongue. It is ulcerated and protruded, with 2.5x2x2cm in size, soft and white-gray surface.

Microscopic Description: Tumor tissue arranges in the form of group or sheets or trabecular of tumor cells. The malignant cells have moderate, light eosinophilic cytoplasm and form keratinized pearls. The nuclei are enlarged, variability in size and shape, containing coarse clumped chromatin with prominent nucleoli. Mitotic figures are common. Tumor invades in lower muscle propria. Stroma is invasion of inflammatory cells.

Diagnosis Details: Squamous cell carcinoma, Grade II, infiltrating muscle propria

Comments:

Formatted Path Reports: HEAD & NECK CHECKLIST

Specimen type: Squamous cell carcinoma of the oral cavity

Tumor Location: Tongue

Tumor grade: Moderately differentiated - grade 2

Tumor extent: Muscularis propria

Lymph nodes: 4/9 Cervical, left

Laterality: Left

Margins: Uninvolved

Lymphovascular invasion: Present

Perineural invasion: Absent

Diagnosis details:

Comments:

ICD-O-3
Carcinoma, squamous cell,
Keratinizing NOS 8071/3
Site: Tongue NOS C02.9
JW 4/12/13

Qual/Syn/chronous Primary		☒

Source: NCI Genomic Data Commons file 0d92dc65-8efb-4ef0-a171-4c764b3b25e9 (TCGA-F7-A61W.C24CD36B-9927-420D-8F21-32F2A938EA89.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).